Surgical pathology report (de-identified scan), TCGA case TCGA-HD-8224, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-HD-8224-01A (Primary Tumor).

[page 1 of 4]
Final Diagnosis

Anterior deep margin of tongue (FSA1), biopsy:
Diffusely infiltrating squamous cell carcinoma.

Middle deep margin of tongue (FSA2):
Diffusely infiltrating squamous cell carcinoma.

Almost total glossectomy with frozen section examination:
Posterior shaved margin positive for squamous cell carcinoma.
Medial shaved margin positive for squamous cell carcinoma.
Areas of lymphovascular invasion are identified.
Perineural invasion identified.
Random sections of tongue show diffuse invasive squamous cell carcinoma extending through multiple areas of the posterior and medial margins.
P16 immunostain will be done on block B2 and reported in an addendum.
Tumor extends all the way to tip of tongue.

Completion of total glossectomy with left lateral border of tongue with new deep and posterior surgical margin with operating room consultation and inking of margins:
New posterior margin positive for squamous cell carcinoma.
New deep margin positive for squamous cell carcinoma.
All inked margins positive for squamous cell carcinoma.

Level 1A lymph node dissection:
Four (4) of 4 lymph nodes positive for squamous cell carcinoma. $4/4^+$

Right level 1B lymph node dissection:
Submandibular salivary gland is negative for malignancy.
Two (2) lymph nodes positive for metastatic squamous cell carcinoma. 2^+

Right level 2A lymph node dissection:
Three (3) of ten (10) lymph nodes positive, several nodes show extensive^{+3/10} extracapsular extension.

Right level 2B lymph node dissection:
Six (6) negative nodes. -6 $+2/4$

Right level 3 lymph node dissection:
Three (3) of four (4) lymph nodes positive. $+1$ $+3/4$

Right level 4 lymph node dissection:
-10 $+2/7$ $+4/7$

55
total
21 positive

[page 2 of 4]
Ten (10) negative nodes.

Left level 1B lymph node dissection:
Unremarkable submandibular salivary gland.
Two (2) positive lymph nodes.

Left level 4 lymph node dissection:
Two (2) of seven (7) lymph nodes positive.

Left level 3 lymph node dissection:
Four (4) of seven (7) lymph nodes positive.

Left level 2B lymph node dissection:
One (1) lymph node positive.

Left level 2A lymph node dissection:
Two (2) of four (4) lymph nodes positive.

Comment: All resected margins were positive for squamous cell carcinoma. This case corresponds to a pathological AJCC stage of T3,N2c.

GENERAL COMMENT REGARDING IMMUNOPEROXIDASE STUDIES: "Performance characteristics for some analytes have been determined by [REDACTED]. They have not been cleared or approved by the U.S Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing."

Clinical Information

Cancer of tongue with mets.

Frozen Section Diagnosis

CA post dorsal tongue.

FSA1: Anterior deep (green) margin (small). Positive for SCC
FSA2: Middle deep (black) margin (larger). Positive for SCC

FSB1 - posterior (shave) - positive.
FSB2 - medial (shave) - positive.

[page 3 of 4]
~80% of shaved margin (+) for CA.

Operating Room Consultation

ORC-C Left lateral tongue with new posterior and deep and anterior margins. [REDACTED]

Gross Description

"FSA1." All frozen section tissue is submitted in cassette "FSA1." Tea bag.

"FSA2." All frozen section tissue is submitted in cassette "FSA2."

"FSB1." All frozen section tissue is submitted in cassette "FSB1."

"FSB2." All frozen section tissue is submitted in cassette "FSB2."

"B, [REDACTED]." The specimen consists of a 5.7 x 4.0 x 2.5 cm right lateral portion of tongue. The posterior margin has previously been inked green, and the medial margin has been inked black. A portion of the deep margin has remained uninked. This area will be inked orange. The surface of the tongue has a gray-tan to white-tan, thickened, nodular appearance. There is a 2.2 x 1.7 cm gray-tan, firm central mass, which extends to the posterior, medial, and deep margins. "B1-B2," mass to include medial and deep margins; "B3-B4," step sections, "B3," central tongue towards anterior tip, "B4," anterior tip; "B5," mass to include deep and posterior margins; "B6," right lateral tongue, representative.

"C, [REDACTED]." The specimen consists of a 5.5 x 6.0 x 3.0 cm left lateral portion of tongue with new posterior, deep, and anterior margins. The tongue has a gray-tan, wrinkled appearance. The new anterior deep margin has previously been inked black, and the new posterior margin has been inked green. Definite tumor is grossly difficult to identify. "C1," posterior margin; "C2," new anterior deep margin; "C3-C5," posterior margin; "C5-C8," anterior deep margin; "C9-C10," anterior deep margin; "C11," posterior tongue; "C12," central tongue; "C13," anterior tongue.

This case is also received with a single yellow cassette labeled [REDACTED]

"D, Level 1A." The specimen consists of a 4.2 x 2.7 x 1.5 cm yellow-tan, fatty fragment. On examination, 4 possible lymph nodes are identified. These range in size from 0.5 to 1.0 cm. "D," 4p, representative.

"E, Right level 1B." The specimen consists of a 4.5 x 3.0 x 2.5 cm grossly unremarkable submandibular gland. On sectioning, the cut surface is yellow-tan and lobulated.

Also free in the container is a 3.0 x 1.5 x 1.0 cm aggregate of yellow, fatty tissue. On examination 2 possible lymph nodes are identified. These measure 0.5 and 0.6 cm. "E1-E2," submandibular gland; "E3," possible lymph nodes, representative.

"F, Right level 2A." The specimen consists of a 6.5 x 2.5 x 1.5 cm aggregate of yellow-tan, fatty tissue. On sectioning, examination, 11 possible lymph nodes are identified. These range in size from 0.2 to 1.5 cm. "F1-F3," fragments, representative.

"G, Right level 2B." The specimen consists of a 4.5 x 2.6 x 1.5 cm fragment of yellow-tan, fatty tissue. On examination, 6 possible lymph nodes are identified. These range in size from 0.3 to 0.6 cm. "G1-G2," fragments, representative.

"H, Right level 3." The specimen consists of a 5.0 x 4.0 x 2.0 cm aggregate of yellow-tan, fatty tissue. On examination, 5 possible lymph nodes are identified. These range in size from 0.5 to 0.7 cm. "H1-H2," fragments, representative.

"I, Right level 4." The specimen consists of a 4.3 x 3.0 x 1.2 cm aggregate of yellow-tan, fatty tissue. Eleven possible lymph nodes are identified. These range in size from 0.2 to 1.0 cm. "I1-I2," fragments, representative.

"J, Left level 1B." The specimen consists of a 4.0 x 3.0 x 2.5 cm grossly unremarkable submandibular gland. On sectioning, the cut surface is yellow-tan and lobulated. Attached to the gland is a 2.7 x 2.5 x 1.0 cm aggregate of yellow-tan, fatty tissue. On examination, 2 possible lymph nodes are identified. These measure 0.3 and 0.4 cm. "J1-J2," submandibular gland; "J3," possible lymph nodes, representative.

"K, Left level 4." The specimen consists of a 4.7 x 3.0 x 1.5 cm aggregate of yellow, fatty tissue. On examination 7 possible lymph nodes are identified. These range in size from 0.5 to 2.3 cm. "K1-K2," fragments, representative.

"L, Left level 3." The specimen consists of a 4.0 x 2.5 x 2.0 cm aggregate of yellow-tan, fatty tissue. On examination, 7

[page 4 of 4]
[REDACTED]

possible lymph nodes are identified. These range in size from 0.3 to 0.7 cm. "L1-L2," fragments, representative.

"M, Left level 2B." The specimen consists of a 3.5 x 2.2 x 1.5 cm aggregate of yellow-tan, fatty tissue. On examination 4 possible lymph nodes are identified. These range in size from 0.7 to 1.5 cm. "M," 4p, representative.

"N, Left level 2A." The specimen consists of a 3.5 x 3.0 x 1.5 cm fragment of yellow, fatty tissue. On examination, a single 2.0 cm lymph node is identified. "N," 1p, representative.

NOTE: SEND THIS CASE TO [REDACTED]

[REDACTED]

Performing Lab

Testing performed at [REDACTED]

Source: NCI Genomic Data Commons file 4f468da7-d4a2-4d71-9d64-ec8e8adacc35 (TCGA-HD-8224.F08A1FE4-9187-45BB-B3EA-17A9A80732B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).